Somatic mutation profile of tumor specimen TARGET-10-PARBRV-09A (aliquot TARGET-10-PARBRV-09A-01D) from TARGET case TARGET-10-PARBRV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,297 days).
Specimen TARGET-10-PARBRV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb852499-6b62-4b99-8d0b-d3824ad73f83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBRV-10A (Blood Derived Normal), aliquot TARGET-10-PARBRV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1495f8e5-9b78-4ec4-9936-34d05407a526

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, RNA 3, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJC6 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs766961674, COSV99674708; called by muse, varscan2
- GABRA6 | c.38+1G>T p.X13_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | catalogued as COSV50888588; called by muse, mutect2
- KRT25 | c.834C>T p.S278= | Splice Region (SNP) | VAF 37/67 reads (55%) | catalogued as rs1172395330; called by muse, mutect2, varscan2
- SCN10A | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767987787, COSV101479260, COSV101479367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN2 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59451232; called by muse, mutect2, varscan2
- FAT1 | c.9018A>T p.K3006N | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KRT23 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRT4 | c.545A>G p.K182R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MACF1 | c.21439C>T p.R7147W (on ENST00000372915; = p.R5192W on NM_012090.5) | Missense Mutation (SNP) | VAF 69/151 reads (46%) | called by muse, mutect2, varscan2
- NEFM | c.1304A>T p.K435M | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- UBA2 | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZFHX4 | c.3601A>C p.K1201Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSM5 | c.471G>C p.R157= | Silent (SNP) | VAF 44/127 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.5115C>G p.L1705= (on ENST00000426542; = p.L1731= on NM_001080479.2) | Silent (SNP) | VAF 17/190 reads (9%) | called by muse, mutect2
- ATRX | c.534C>A p.V178= | Silent (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- FEZ1 | c.351C>A p.L117= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99630732; called by muse, mutect2, varscan2
- BOD1P2 | n.87G>A | RNA (SNP) | VAF 21/50 reads (42%) | catalogued as rs1477034454; called by muse, mutect2, varscan2
- CST9LP1 | n.186C>A | RNA (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.1177G>T | RNA (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- ZC2HC1A | c.705-3222C>A | Intron (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
